Somatic mutation profile of tumor specimen TCGA-PG-A6IB-01A (aliquot TCGA-PG-A6IB-01A-21D-A31U-09) from TCGA case TCGA-PG-A6IB, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 68.4 years (24,969 days).
Specimen TCGA-PG-A6IB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 646f2c9e-996a-4354-891f-5561139bcf84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PG-A6IB-10A (Blood Derived Normal), aliquot TCGA-PG-A6IB-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be29a1cb-ab30-4c05-b259-e815f98955ca

The open-access MAF lists 547 somatic variants for this specimen: 403 protein-altering or splice-affecting, 129 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 280, Silent 129, Frame Shift Del 74, Frame Shift Ins 15, Nonsense Mutation 13, Splice Site 11, In Frame Del 7, Intron 5, RNA 4, 5'Flank 3, Splice Region 3, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 36/99 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CCND1 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57119829, COSV99919330; called by muse, mutect2, varscan2
- PAX2 | c.76del p.V26Cfs*3 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | catalogued as rs75462234, COSV62291007; ClinVar: pathogenic; called by mutect2, pindel
- PIK3R1 | c.1746-2A>G p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 10/47 reads (21%) | hotspot (GDC flag); catalogued as COSV57125460, COSV57131831, COSV57142185; called by muse, mutect2, varscan2
- PTEN | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 26/100 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398123322, COSV64289089, COSV64294277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by mutect2, varscan2
- RYR1 | c.14129+1G>A p.X4710_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as rs142929172, COSV62110710; ClinVar: pathogenic; called by muse, mutect2
- ABCB5 | c.2896A>G p.M966V (on ENST00000404938 / NM_001163941.2; = p.M521V on NM_178559.6) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99328559; called by muse, mutect2, varscan2
- ABHD14A | c.747T>G p.H249Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99865434; called by muse, mutect2, varscan2
- AC090517.4 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.615); catalogued as COSV99974584; called by muse, mutect2, varscan2
- ACACB | c.7172C>T p.A2391V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100622986; called by muse, mutect2, varscan2
- ACOT11 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760730473, COSV100156943; called by muse, mutect2, varscan2
- ACP5 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as COSV99520362; called by muse, mutect2
- ADAM19 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs770714695, COSV99977450; called by muse, mutect2, varscan2
- ADAMTS17 | c.790-2A>G p.X264_splice | Splice Site (SNP) | VAF 17/47 reads (36%) | catalogued as rs772850171, COSV51478519; called by muse, mutect2, varscan2
- ADAMTS7 | c.2852G>A p.W951* | Nonsense Mutation (SNP) | VAF 59/194 reads (30%) | catalogued as COSV101183116; called by muse, mutect2, varscan2
- ADCY1 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV99812137; called by muse, mutect2, varscan2
- ADGRF5 | c.3822G>T p.Q1274H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99345730; called by muse, mutect2, varscan2
- AEBP1 | c.3172G>A p.A1058T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV99788827; called by muse, mutect2, varscan2
- AHNAK2 | c.6415C>A p.L2139M | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.984); catalogued as rs566910319, COSV100317745; called by muse, mutect2, varscan2
- ALDH9A1 | c.821C>A p.P274H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.056); catalogued as COSV100699302, COSV61341065; called by muse, mutect2, varscan2
- ALG10B | c.1409G>T p.R470M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100439917; called by muse, mutect2, varscan2
- AMMECR1L | c.766G>T p.G256C | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99761406; called by muse, mutect2, varscan2
- ANK3 | c.7501C>T p.R2501W | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.543); catalogued as rs759280618, COSV55073423; called by muse, mutect2, varscan2
- ANKRD11 | c.7739A>G p.D2580G | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99969571; called by muse, mutect2
- ANKRD36B | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as rs369666439; called by muse, mutect2, varscan2
- ANKRD6 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1185100363, COSV100329995; called by muse, mutect2, varscan2
- AQR | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV99334031; called by muse, mutect2, varscan2
- ARFGEF2 | c.1834C>T p.R612W | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.586); catalogued as rs370911063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF1 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs781793490, COSV100529049; called by muse, mutect2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | catalogued as COSV61372705; called by mutect2, pindel, varscan2
- ARMC8 | c.76G>A p.D26N (on ENST00000469044 / NM_001363941.2; = p.D12N on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100627678; called by muse, mutect2, varscan2
- ASPG | c.1075del p.E359Rfs*2 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | catalogued as COSV101496412; called by mutect2, pindel, varscan2
- ASTN1 | c.3127T>C p.W1043R | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100706972; called by muse, mutect2
- ATP2C2 | c.2005G>A p.V669M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs772764894, COSV99298164; called by muse, mutect2, varscan2
- ATRNL1 | c.1919G>A p.C640Y | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100745815; called by muse, mutect2, varscan2
- AXIN2 | c.1352G>A p.G451D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100196566; called by muse, mutect2, varscan2
- B4GALNT3 | c.2731C>T p.H911Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.699); catalogued as COSV99843104; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs755506199; called by mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BTNL8 | c.1075C>T p.R359W | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs770261754, COSV51456838; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C2orf80 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.178); catalogued as COSV100378443; called by muse, mutect2, varscan2
- C6orf118 | c.1004G>T p.R335M | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100024568; called by muse, mutect2, varscan2
- CACNA1E | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1161110769, COSV100702987; called by muse, mutect2, varscan2
- CACNG3 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99136367; called by muse, mutect2
- CAPN15 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.738); catalogued as rs142621545, COSV54838932; called by muse, mutect2, varscan2
- CARD16 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs889939311, COSV65212709; called by muse, mutect2, varscan2
- CBLN3 | c.206del p.P69Lfs*35 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | catalogued as rs1268177561; called by pindel, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC88B | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs762834768, COSV57264752; called by muse, mutect2, varscan2
- CCNT1 | c.813C>A p.D271E | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV99980776; called by muse, mutect2
- CCSER1 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs200732825; called by muse, mutect2, varscan2
- CD81 | c.629T>G p.I210S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV99719215, COSV99719283; called by muse, mutect2, varscan2
- CDC42EP4 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs192997713, COSV100231841; called by muse, mutect2, varscan2
- CDKAL1 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV99215604; called by muse, mutect2
- CDX2 | c.916del p.V306Cfs*2 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | catalogued as rs773511514; called by mutect2, pindel, varscan2
- CES5A | c.1558C>T p.Q520* (on ENST00000290567 / NM_001143685.2; = p.Q470* on NM_145024.3) | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as rs781421042, COSV99307615; called by muse, mutect2, varscan2
- CFAP47 | c.5296G>A p.V1766M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.63); catalogued as COSV100545399, COSV57974526; called by muse, mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CFAP69 | c.1313A>G p.Y438C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100290162; called by muse, mutect2, varscan2
- CFP | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1421325518, COSV99901485; called by muse, mutect2, varscan2
- CHGA | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.096); catalogued as COSV99381174; called by muse, mutect2, varscan2
- CHL1 | c.2788G>A p.D930N (on ENST00000397491 / NM_001253387.1; = p.D946N on NM_006614.4) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.132); catalogued as COSV99851411, COSV99852215; called by muse, mutect2, varscan2
- CHRM1 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as COSV100186203; called by muse, mutect2, varscan2
- CHST13 | c.349T>A p.C117S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100081215; called by muse, mutect2, varscan2
- CLVS1 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.088); catalogued as COSV100370081; called by muse, mutect2, varscan2
- CNGA2 | c.591T>G p.G197= | Splice Region (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100323727; called by muse, mutect2
- CNGA2 | c.683T>A p.I228N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100323730; called by muse, mutect2, varscan2
- CNGB3 | c.1782C>A p.S594R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100182114; called by muse, mutect2
- CNNM1 | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1471113428, COSV63200969; called by muse, mutect2, varscan2
- CNNM4 | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs755932169, COSV100998690; called by muse, varscan2
- CNTNAP1 | c.2959C>A p.L987I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV99226517; called by muse, mutect2, varscan2
- COL6A2 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as rs1267725555, COSV56000055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPS7A | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as rs151177416; called by muse, varscan2
- CRB2 | c.2324G>A p.C775Y | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100749662; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 36/86 reads (42%) | catalogued as rs769538822; called by mutect2, varscan2
- CSDE1 | c.1426G>A p.D476N (on ENST00000358528 / NM_001007553.3; = p.D445N on NM_007158.6) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV99795168; called by muse, mutect2, varscan2
- CSF3R | c.1750G>T p.G584C | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100117779; called by muse, mutect2, varscan2
- CSNK1G2 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99729960; called by muse, mutect2, varscan2
- CTNNA3 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101049879; called by muse, mutect2, varscan2
- CUBN | c.2528G>T p.R843M | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.592); catalogued as COSV100912806; called by muse, mutect2, varscan2
- CUX1 | c.3913A>G p.I1305V | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as COSV99471765; called by muse, mutect2, varscan2
- CXorf21 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs149817919, COSV66762899; called by muse, mutect2, varscan2
- CYFIP2 | c.3208C>T p.R1070W (on ENST00000616178 / NM_001291722.2; = p.R1045W on NM_014376.4) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs764928113, COSV59031408; called by muse, mutect2, varscan2
- DAP | c.256A>G p.M86V | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs748465213, COSV99136339; called by muse, mutect2, varscan2
- DCAF12L1 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV100948328; called by muse, mutect2, varscan2
- DMXL1 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.099); catalogued as COSV100224137; called by muse, mutect2, varscan2
- DNAH17 | c.1340del p.G447Afs*11 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | catalogued as COSV101102038; called by mutect2, pindel, varscan2
- DNAH9 | c.7864G>A p.A2622T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.777); catalogued as COSV99306151; called by muse, mutect2, varscan2
- DNAH9 | c.10886C>T p.S3629F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs776946486, COSV99306154; called by muse, mutect2, varscan2
- DNAJC17 | c.308G>C p.R103P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99591703; called by muse, varscan2
- DOCK10 | c.5099G>T p.R1700M | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV99289786; called by muse, mutect2, varscan2
- DOK7 | c.298T>C p.W100R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755542078, COSV100403372; called by muse, mutect2, varscan2
- DOP1B | c.6785C>T p.A2262V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV101214444, COSV67690917; called by muse, mutect2, varscan2
- DPPA4 | c.444del p.K148Nfs*2 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | catalogued as rs762470455; called by mutect2, varscan2
- DST | c.17740G>A p.D5914N (on ENST00000361203 / NM_001374722.1; = p.D3611N on NM_015548.5) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as rs753185411, COSV99756829; called by muse, mutect2, varscan2
- DYNC1H1 | c.5660G>A p.R1887H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768520247, COSV100794986; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2I2 | c.562T>C p.W188R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100823637; called by muse, mutect2, varscan2
- EDA2R | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99490713; called by muse, mutect2, varscan2
- EGFL7 | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs536328944, COSV100451989; called by muse, mutect2
- EHMT1 | c.2335G>A p.A779T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV58382340; called by muse, mutect2, varscan2
- EHMT2 | c.2419C>T p.R807W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs770418733, COSV100977145; called by muse, mutect2, varscan2
- EIF2AK3 | c.2882C>T p.A961V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); catalogued as COSV100303778; called by muse, mutect2, varscan2
- ELMO3 | c.475C>T p.R159C (on ENST00000652269; = p.R106C on NM_024712.5) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV100681712; called by muse, mutect2, varscan2
- EML5 | c.658A>G p.I220V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1353326958, COSV100715713; called by mutect2, varscan2
- EPC1 | c.2329A>T p.I777L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99552994; called by muse, mutect2, varscan2
- EPHA8 | c.1604-1G>A p.X535_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | catalogued as COSV99384958; called by muse, mutect2, varscan2
- EPHB1 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.766); catalogued as rs1245944825, COSV101213228, COSV67664069; called by muse, mutect2, varscan2
- EVA1A | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as rs543965376, COSV52062192; called by muse, varscan2
- FAM166A | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs371213582; called by muse, mutect2, varscan2
- FAM241B | c.208C>A p.Q70K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.954); catalogued as COSV100958410; called by mutect2, varscan2
- FAM71B | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV100262143; called by muse, mutect2, varscan2
- FAT3 | c.11866A>G p.I3956V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749543319, COSV99966826; called by muse, mutect2, varscan2
- FAT4 | c.13534G>T p.G4512C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100628822; called by muse, mutect2, varscan2
- FBXW12 | c.505dup p.T169Nfs*44 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as rs767006036; called by mutect2, varscan2
- FGF21 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99711472; called by muse, mutect2, varscan2
- FGFRL1 | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201440347, COSV99294681; called by muse, mutect2, varscan2
- FGR | c.1018+1G>C p.X340_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100925843; called by muse, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FN1 | c.5849G>A p.R1950Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs746145647, COSV100117287; called by muse, mutect2, varscan2
- FNBP1 | c.983del p.N328Ifs*7 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | catalogued as rs771301424; called by mutect2, varscan2
- FNDC1 | c.4327dup p.T1443Nfs*81 | Frame Shift Ins (INS) | VAF 18/77 reads (23%) | catalogued as rs1410233255; called by mutect2, varscan2
- FOXE3 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100624022; called by muse, mutect2
- FRMPD3 | c.1424A>G p.E475G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99346414; called by muse, mutect2, varscan2
- FZD5 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99776294; called by muse, mutect2, varscan2
- GALNT8 | c.1016C>A p.P339Q | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV52896802, COSV99362875, COSV99363277; called by muse, mutect2, varscan2
- GAS2L2 | c.1226del p.P409Lfs*92 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as rs782212939; called by mutect2, pindel, varscan2
- GAS7 | c.1288C>T p.R430W (on ENST00000432992 / NM_201433.2; = p.R290W on NM_003644.3) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs747566446, COSV100095790; called by muse, mutect2
- GBF1 | c.1861C>T p.R621* (on ENST00000369983 / NM_001377137.1; = p.R620* on NM_004193.3) | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as rs766618538, COSV64143766; called by muse, mutect2, varscan2
- GFRA1 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62608358; called by muse, mutect2, varscan2
- GGA3 | c.517_519del p.E173del (on ENST00000537686 / NM_138619.4; = p.E140del on NM_014001.5) | In Frame Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs775155412; called by pindel, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLT6D1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100874541; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs749150409; called by mutect2, varscan2
- GOLIM4 | c.1891del p.R631Gfs*87 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs1210775698; called by mutect2, pindel, varscan2
- GPR155 | c.2235G>T p.E745D | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.976); catalogued as COSV99789945; called by muse, mutect2, varscan2
- GPR61 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV63983497; called by muse, mutect2, varscan2
- GRB7 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100485530; called by muse, mutect2, varscan2
- GRIN2B | c.2776C>T p.R926* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as rs1555102536, COSV74206888, COSV74207401; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GSE1 | c.658A>G p.R220G | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99496673; called by mutect2, varscan2
- GSG1L | c.551-2A>G p.X184_splice (on ENST00000447459 / NM_001109763.2; = p.X29_splice on NM_144675.2) | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as COSV101093745; called by muse, mutect2, varscan2
- GZMM | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556484742, COSV99198840; called by muse, mutect2, varscan2
- HCFC1 | c.2723C>T p.T908M | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60078158; called by muse, mutect2
- HLA-A | c.627dup p.K210Qfs*11 | Frame Shift Ins (INS) | VAF 22/191 reads (12%) | catalogued as rs199474609; called by mutect2, varscan2
- HLTF | c.149C>G p.T50S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV100026873; called by muse, mutect2, varscan2
- HMGCR | c.780+2T>C p.X260_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99843288; called by muse, mutect2, varscan2
- HTR3D | c.997G>A p.V333M (on ENST00000382489 / NM_001163646.2; = p.V158M on NM_182537.3) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.867); catalogued as rs767685576, COSV61915081; called by muse, mutect2, varscan2
- HUWE1 | c.5870A>G p.H1957R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.888); catalogued as rs1182244853, COSV99472639; called by muse, mutect2, varscan2
- IFI30 | c.693C>T p.G231= | Splice Region (SNP) | VAF 12/45 reads (27%) | catalogued as COSV101325315; called by muse, mutect2, varscan2
- IGHG2 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs587758396; called by muse, mutect2, varscan2
- IGSF9 | c.1883G>A p.R628Q (on ENST00000368094 / NM_001135050.2; = p.R612Q on NM_020789.4) | Missense Mutation (SNP) | VAF 106/289 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.169); catalogued as COSV100829632; called by muse, mutect2, varscan2
- IGSF9 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs770440294, COSV100829634; called by muse, varscan2
- IK | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772004082, COSV101341789; called by muse, mutect2, varscan2
- IL27RA | c.1154T>C p.V385A | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1461729252, COSV99652194; called by muse, mutect2, varscan2
- IL7R | c.222-2A>G p.X74_splice | Splice Site (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100286309; called by muse, mutect2, varscan2
- INSR | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as CM930438, COSV100252408; called by muse, mutect2, varscan2
- IRS1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762833254, COSV100524451; called by muse, mutect2
- JAM3 | c.745del p.V249Ffs*10 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | catalogued as rs763250381; called by mutect2, pindel, varscan2
- KARS1 | c.830del p.G277Efs*16 | Frame Shift Del (DEL) | VAF 21/68 reads (31%) | catalogued as rs1567500406; called by mutect2, pindel, varscan2
- KAT6A | c.4150G>A p.V1384M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.479); catalogued as rs752818339, COSV99704725; called by muse, varscan2
- KCNG4 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537957795, COSV100376995; called by muse, mutect2, varscan2
- KCNMB2 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV100843962; called by muse, mutect2, varscan2
- KIAA1841 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1443293001, COSV54372503; called by muse, mutect2, varscan2
- KIF17 | c.2911+1G>A p.X971_splice | Splice Site (SNP) | VAF 8/41 reads (20%) | catalogued as COSV56117234, COSV99929161; called by muse, mutect2, varscan2
- KIF21B | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs182269799; called by muse, mutect2, varscan2
- KLHL41 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.431); catalogued as COSV99500409; called by muse, mutect2, varscan2
- KRT17 | c.65del p.G22Afs*93 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | catalogued as rs753167272; called by mutect2, pindel, varscan2
- KTI12 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as COSV100860204, COSV65405981; called by muse, mutect2, varscan2
- LAMA5 | c.6350G>T p.C2117F | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1243162596, COSV99440379; called by muse, mutect2, varscan2
- LAMB1 | c.2713G>A p.D905N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.182); catalogued as rs765478571, COSV55961899; called by mutect2, varscan2
- LGALS9 | c.560C>A p.A187D (on ENST00000395473 / NM_009587.3; = p.A155D on NM_002308.4) | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV100119468; called by muse, mutect2
- LIN37 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1460751330, COSV99137456; called by muse, mutect2
- LIPE | c.1318del p.V440Yfs*123 | Frame Shift Del (DEL) | VAF 18/63 reads (29%) | catalogued as rs1435074806; called by mutect2, pindel, varscan2
- LRRC4B | c.1022A>G p.H341R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100975933; called by muse, mutect2, varscan2
- LRRC7 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.281); catalogued as rs753073868, COSV100201168; called by muse, varscan2
- LRRIQ1 | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101277721; called by muse, mutect2, varscan2
- LYSMD4 | c.146G>A p.R49Q (on ENST00000409796 / NM_001284417.2; = p.G20S on NM_152449.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1222674240, COSV100230628; called by muse, mutect2, varscan2
- MACF1 | c.18917T>C p.M6306T (on ENST00000372915; = p.M4351T on NM_012090.5) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99244790; called by muse, mutect2, varscan2
- MAGEC3 | c.685G>C p.A229P | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100025517; called by muse, mutect2, varscan2
- MAP1B | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs139604402, COSV57101435; called by muse, mutect2
- MAP3K13 | c.1009T>C p.W337R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99407284; called by muse, mutect2, varscan2
- MAP4K4 | c.2426C>T p.T809M (on ENST00000347699 / NM_001242559.2; = p.T727M on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs372783884; called by muse, mutect2, varscan2
- MAP4K4 | c.3047C>G p.T1016S (on ENST00000347699 / NM_001242559.2; = p.T934S on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.349); catalogued as COSV100154982; called by muse, mutect2, varscan2
- MAP4K5 | c.1643A>G p.Q548R | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.301); catalogued as rs766405010, COSV99184698; called by muse, mutect2, varscan2
- MAP7D1 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100294548; called by muse, mutect2
- MAST2 | c.2501A>G p.D834G | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV100788287; called by muse, mutect2, varscan2
- MCF2 | c.1837-1G>A p.X613_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV58494234; called by muse, mutect2, varscan2
- MCMDC2 | c.1182C>A p.S394R | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV100551987; called by muse, mutect2, varscan2
- MGAM | c.280A>G p.N94D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV101516445; called by muse, mutect2, varscan2
- MOGS | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.877); catalogued as rs1212011793, COSV99270554; called by muse, mutect2, varscan2
- MSH4 | c.2315G>A p.G772D | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99591790; called by muse, mutect2, varscan2
- MUC6 | c.2524C>A p.L842I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.242); catalogued as COSV101424633; called by muse, mutect2, varscan2
- MYCBP2 | c.1654G>A p.D552N (on ENST00000357337; = p.D590N on NM_015057.5) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100630530; called by muse, mutect2, varscan2
- MYOM2 | c.3742C>T p.R1248* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | catalogued as COSV50729926, COSV50792917; called by muse, mutect2, varscan2
- N4BP2 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99788764; called by muse, mutect2, varscan2
- NALCN | c.3056del p.L1019Wfs*7 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs772394714; called by mutect2, varscan2
- NDUFA12 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100580858; called by muse, mutect2, varscan2
- NFS1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs764420057, COSV60764640; called by muse, mutect2, varscan2
- NIPAL4 | c.1144A>G p.M382V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV99977447; called by muse, mutect2, varscan2
- NKAPL | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1355044313, COSV59197153; called by muse, mutect2, varscan2
- NMNAT1 | c.237G>T p.W79C | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV101020424; called by muse, mutect2, varscan2
- NOBOX | c.487del p.R163Afs*11 | Frame Shift Del (DEL) | VAF 43/153 reads (28%) | catalogued as rs754069719; called by mutect2, pindel, varscan2
- NOMO2 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs920661495, COSV100395681; called by mutect2, varscan2
- NOTCH1 | c.5800C>A p.L1934M | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99488584; called by muse, mutect2, varscan2
- NPHS1 | c.1165A>G p.M389V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV62289886; called by muse, mutect2, varscan2
- NPPA | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs143419574; called by muse, mutect2, varscan2
- NR4A2 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs568311354, COSV100277212; called by muse, mutect2, varscan2
- NRDE2 | c.2788G>C p.V930L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs770150434, COSV100583503; called by muse, mutect2, varscan2
- NSD2 | c.2423C>T p.S808F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100373424, COSV100373804; called by muse, mutect2, varscan2
- OBSCN | c.2690G>A p.R897H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs368190577, COSV52816605; called by muse, mutect2, varscan2
- OBSCN | c.4894G>A p.A1632T | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.173); catalogued as COSV99479426; called by muse, mutect2, varscan2
- OBSCN | c.15565G>A p.V5189M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs181180369; called by muse, mutect2, varscan2
- OPHN1 | c.1313G>A p.S438N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as COSV100830506; called by muse, mutect2, varscan2
- OR10G4 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs1380082806, COSV100304847, COSV57976560; called by muse, mutect2
- OR1A2 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV101126367, COSV67936872; called by muse, mutect2, varscan2
- OR51E2 | c.952G>T p.G318* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as COSV67807049; called by muse, mutect2, varscan2
- OR51F2 | c.644G>A p.C215Y | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as COSV100438052; called by muse, mutect2, varscan2
- OR52L1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as COSV100176199; called by muse, mutect2, varscan2
- OSR1 | c.434G>C p.G145A | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0.11); catalogued as COSV99693704; called by muse, mutect2, varscan2
- OTX1 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56995814; called by muse, mutect2, varscan2
- OVGP1 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100868166; called by muse, mutect2, varscan2
- PCDHB13 | c.1610G>A p.G537D | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53393343, COSV99507359; called by muse, mutect2, varscan2
- PCDHGB7 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs966922299, COSV99539490; called by muse, mutect2
- PCSK4 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149717479; called by muse, mutect2, varscan2
- PDE2A | c.2500G>A p.G834R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57812090; called by muse, mutect2
- PDPR | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV99848421; called by muse, mutect2, varscan2
- PER1 | c.2803C>T p.P935S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as rs1382724315, COSV57918742, COSV57920570; called by muse, mutect2, varscan2
- PEX2 | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); catalogued as COSV100824794; called by muse, mutect2, varscan2
- PHLDA3 | c.260G>A p.C87Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV100943623; called by muse, mutect2, varscan2
- PHLDB2 | c.3506G>A p.R1169Q (on ENST00000393925 / NM_001134439.2; = p.R1126Q on NM_145753.2) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as rs140319291; called by muse, varscan2
- PITPNB | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV58060951; called by muse, mutect2, varscan2
- PKD2 | c.826A>G p.M276V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs745604753, COSV99417440; called by muse, varscan2
- PLCB4 | c.1155del p.F385Lfs*4 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | catalogued as rs35771445; called by mutect2, pindel, varscan2
- PLEKHA7 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100773121; called by muse, mutect2, varscan2
- PLEKHG4 | c.1544C>A p.P515Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.809); catalogued as COSV100846506, COSV64613374; called by muse, mutect2, varscan2
- PLXNB1 | c.4274G>A p.C1425Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99602935; called by muse, mutect2, varscan2
- POLDIP2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.647); catalogued as rs1323924980, COSV99134800; called by muse, mutect2, varscan2
- POLR2A | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs764559155; called by muse, mutect2, varscan2
- PON2 | c.195del p.F65Lfs*5 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs1201102139; called by mutect2, pindel, varscan2
- PPP1R3A | c.1510G>T p.G504* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV99493087; called by muse, mutect2, varscan2
- PPP4R1 | c.701C>T p.A234V (on ENST00000400556 / NM_001042388.3; = p.A217V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53282127; called by muse, mutect2, varscan2
- PPP6R2 | c.2561del p.P854Rfs*23 (on ENST00000216061 / NM_001365836.1; = p.P820Rfs*23 on NM_014678.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | catalogued as COSV53291064; called by mutect2, pindel, varscan2
- PRKAG2 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.091); catalogued as COSV99835416; called by muse, mutect2, varscan2
- PRSS38 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs373887552; called by muse, mutect2, varscan2
- PSD | c.2332C>T p.R778W | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.249); catalogued as rs759227476, COSV99192775; called by muse, mutect2, varscan2
- PSMB5 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100557365; called by muse, mutect2, varscan2
- PTPN23 | c.1823del p.K608Sfs*5 | Frame Shift Del (DEL) | VAF 32/101 reads (32%) | catalogued as COSV55543498; called by mutect2, pindel, varscan2
- PTPRT | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1419824411, COSV62031852; called by muse, mutect2, varscan2
- PXDNL | c.35_38del p.F12Sfs*28 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs1563327660; called by mutect2, varscan2
- RAB11FIP3 | c.1153G>T p.G385W | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV51933121, COSV99240435; called by muse, mutect2, varscan2
- RAB27B | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs778920751, COSV100024220; called by muse, mutect2, varscan2
- RABGAP1L | c.1824G>T p.K608N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99270851; called by muse, mutect2, varscan2
- RABL6 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV100273405; called by muse, mutect2
- RAI1 | c.3199C>T p.R1067C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs745616113, COSV99884185; called by muse, varscan2
- RARS2 | c.512T>G p.L171R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101057317; called by muse, mutect2, varscan2
- RASAL3 | c.2974C>T p.R992W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs775451877, COSV54604421; called by muse, mutect2, varscan2
- RAVER2 | c.1043A>G p.N348S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.077); catalogued as COSV99605268; called by muse, mutect2, varscan2
- RBM15 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100873453; called by mutect2, varscan2
- RHBG | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs774514973, COSV54803104; called by muse, mutect2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 23/69 reads (33%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF17 | c.4497G>T p.K1499N | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99693216; called by muse, mutect2
- RNF213 | c.8429G>A p.S2810N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100300698; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RTP5 | c.1412G>A p.C471Y | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100574742; called by muse, mutect2, varscan2
- RUBCN | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99584170; called by muse, mutect2, varscan2
- RUNX3 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs764020894, COSV58243694; called by muse, mutect2, varscan2
- RYR3 | c.4682C>T p.T1561M | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs577412857, COSV101212036, COSV66806450; called by muse, mutect2, varscan2
- SAFB2 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs149456738; called by muse, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 34/112 reads (30%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCN5A | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs776363986, CM1212293, COSV100348752; called by muse, mutect2, varscan2
- SEL1L2 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV99533332; called by muse, mutect2, varscan2
- SERGEF | c.1191G>T p.L397F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.99); catalogued as COSV99787344; called by muse, mutect2, varscan2
- SERPINF1 | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV99628849; called by muse, mutect2
- SFMBT2 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs781238083, COSV62812131; called by muse, varscan2
- SFXN1 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs769920329, COSV58495202; called by muse, mutect2, varscan2
- SHPRH | c.1441A>G p.S481G | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV99262170; called by muse, mutect2, varscan2
- SHROOM2 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.471); catalogued as rs370184337, COSV101098715; called by muse, mutect2, varscan2
- SIPA1L1 | c.172del p.R58Efs*8 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs1567251966; called by pindel, varscan2
- SLC11A2 | c.427G>A p.V143M (on ENST00000394904 / NM_001379455.1; = p.V114M on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV100014760; called by muse, mutect2, varscan2
- SLC17A1 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs779978733, COSV99765819; called by muse, mutect2, varscan2
- SLC19A3 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51452800; called by muse, mutect2, varscan2
- SLC1A5 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101314785; called by muse, mutect2, varscan2
- SLC22A3 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | catalogued as rs373997883, COSV51715505; called by muse, mutect2, varscan2
- SLC38A10 | c.504C>T p.I168= | Splice Region (SNP) | VAF 11/29 reads (38%) | catalogued as rs766902328, COSV55846283; called by muse, varscan2
- SLC38A8 | c.445C>A p.Q149K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as rs146899328, COSV100230538; called by muse, mutect2, varscan2
- SLC44A3 | c.857G>A p.G286E (on ENST00000271227 / NM_001114106.3; = p.G238E on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs1365284462, COSV99598255; called by muse, mutect2, varscan2
- SLC47A2 | c.1057G>T p.G353W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100328045; called by muse, mutect2
- SLC4A3 | c.2939C>A p.P980H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as COSV56097366, COSV99812897; called by muse, mutect2, varscan2
- SLC8A2 | c.1473G>T p.Q491H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV99370019; called by muse, mutect2, varscan2
- SLC9B2 | c.173A>C p.K58T | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV100294119; called by muse, mutect2, varscan2
- SMARCA4 | c.2928G>C p.L976F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758606; called by muse, mutect2, varscan2
- SMARCB1 | c.214dup p.T72Nfs*4 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | catalogued as CI125933; called by mutect2, varscan2
- SMCHD1 | c.5403T>A p.F1801L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV99861824; called by muse, mutect2, varscan2
- SMG6 | c.4150C>T p.R1384W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866312155, COSV99558269; called by muse, mutect2, varscan2
- SNAP25 | c.145A>G p.M49V | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV54773606, COSV54774395; called by muse, mutect2, varscan2
- SORCS1 | c.2572G>A p.V858I | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as rs201889963, COSV53879347; called by muse, mutect2, varscan2
- SOX30 | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.02); catalogued as COSV99398505; called by muse, mutect2
- SP110 | c.1591-2A>G p.X531_splice | Splice Site (SNP) | VAF 11/56 reads (20%) | catalogued as COSV99283479; called by muse, mutect2, varscan2
- SPATA4 | c.288_290del p.S97del | In Frame Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs745487762; called by pindel, varscan2
- SPPL2C | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1051606044, COSV100234057; called by muse, mutect2, varscan2
- SRRM2 | c.6757G>A p.A2253T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV99241511; called by muse, mutect2, varscan2
- SRRM4 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as rs1264509973, COSV57428592; called by muse, mutect2, varscan2
- TBX2 | c.1472T>C p.L491P | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99538908; called by muse, mutect2, varscan2
- TIMM17B | c.212dup p.L72Pfs*56 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | catalogued as rs782500597; called by mutect2, varscan2
- TMC4 | c.929G>A p.R310Q (on ENST00000617472 / NM_001145303.3; = p.R304Q on NM_144686.4) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.053); catalogued as rs761508623, COSV56599007, COSV56603742; called by muse, mutect2, varscan2
- TMOD3 | c.282del p.I97Yfs*23 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs759399045; called by mutect2, varscan2
- TNK2 | c.2432C>A p.P811H | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57369661; called by muse, mutect2, varscan2
- TOLLIP | c.610G>T p.G204W | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.936); catalogued as COSV99719595; called by muse, mutect2, varscan2
- TOR2A | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs770165869, COSV60162579; called by muse, varscan2
- TRAK1 | c.2021G>A p.C674Y | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100565663; called by muse, mutect2
- TRAPPC9 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs201233141, COSV66900085; ClinVar: uncertain significance; called by muse, varscan2
- TRIP12 | c.3611T>C p.I1204T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs182681439, COSV99390389; called by muse, mutect2, varscan2
- TRMT2B | c.407T>G p.L136R | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV100105397; called by muse, mutect2, varscan2
- TRPM3 | c.4505G>A p.R1502H (on ENST00000357533 / NM_001366142.2; = p.R1357H on NM_020952.6) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs138749288; called by muse, mutect2
- TTLL8 | c.983G>A p.C328Y | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99838377; called by muse, mutect2
- TUBA3D | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs550660894, COSV58311444; called by muse, mutect2, varscan2
- TUBA4A | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); catalogued as COSV99944805; called by muse, mutect2, varscan2
- UACA | c.2015A>T p.E672V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100537549; called by muse, mutect2, varscan2
- USH1C | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs372497947, CM1310702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP39 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100083851; called by muse, mutect2, varscan2
- USP48 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57608875; called by muse, varscan2
- VAMP2 | c.22G>C p.A8P | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1266146036, COSV100336106; called by muse, mutect2, varscan2
- VASN | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs1242261031, COSV99227729; called by muse, mutect2, varscan2
- VAV1 | c.1472T>C p.L491S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV100409118; called by muse, mutect2, varscan2
- VPS35L | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs757124401, COSV99220893; called by muse, mutect2, varscan2
- WDR5 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1395151174, COSV100681907; called by muse, mutect2, varscan2
- WFDC5 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.076); catalogued as rs374696524; called by muse, mutect2, varscan2
- XYLT2 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as COSV99190954; called by muse, mutect2, varscan2
- ZBTB6 | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV65409974; called by muse, mutect2, varscan2
- ZFHX4 | c.3199C>A p.R1067S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99263455; called by muse, mutect2, varscan2
- ZFHX4 | c.9442C>A p.L3148M | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV99263458; called by muse, mutect2
- ZFP28 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.094); catalogued as COSV100019628; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as rs753611080; called by mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 22/46 reads (48%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZMYM5 | c.156A>T p.E52D | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV100562710; called by muse, mutect2, varscan2
- ZNF197 | c.1124G>A p.C375Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100482109; called by mutect2, varscan2
- ZNF224 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.926); catalogued as rs199606564, COSV100425419; called by muse, mutect2, varscan2
- ZNF248 | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100627622; called by muse, mutect2, varscan2
- ZNF335 | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs911357250, COSV100532796; called by muse, mutect2, varscan2
- ZNF366 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.745); catalogued as rs773571362, COSV59214236; called by muse, mutect2, varscan2
- ZNF415 | c.1327A>G p.N443D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99701651; called by muse, mutect2, varscan2
- ZNF45 | c.833G>A p.C278Y | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs1257642165, COSV99524160; called by muse, mutect2, varscan2
- ZNF536 | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs762711518, COSV62821482; called by muse, varscan2
- ZNF549 | c.1133G>A p.R378Q (on ENST00000376233 / NM_001199295.2; = p.R365Q on NM_153263.2) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.3); catalogued as rs199998659, COSV53723486; called by muse, mutect2, varscan2
- ZNF689 | c.524del p.K175Sfs*102 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as COSV54908979; called by mutect2, pindel, varscan2
- ZNF703 | c.1540G>T p.A514S | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as rs974399085, COSV100521745; called by muse, varscan2
- ZNF98 | c.318del p.V107* | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | catalogued as COSV100757456; called by mutect2, pindel, varscan2
- ZWILCH | c.1754G>T p.C585F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100328707; called by muse, varscan2
- ALS2 | c.4071dup p.G1358Wfs*9 | Frame Shift Ins (INS) | VAF 12/64 reads (19%) | called by mutect2, pindel, varscan2
- ARID1A | c.4689dup p.M1564Hfs*8 | Frame Shift Ins (INS) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- BOLA3 | c.97del p.E33Sfs*4 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by pindel, varscan2
- CNGA2 | c.1873del p.A625Pfs*16 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- CNTN2 | c.1699_1701del p.E567del | In Frame Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- COL25A1 | c.1542del p.G515Efs*14 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- DHX36 | c.259A>G p.M87V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.155); called by muse, mutect2
- DLG3 | c.2204_2206del p.Q735del (on ENST00000374360 / NM_021120.4; = p.Q430del on NM_020730.3) | In Frame Del (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel, varscan2
- EFCAB5 | c.2251del p.I751* | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | called by mutect2, pindel, varscan2
- EPHA10 | c.2188del p.A730Pfs*18 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- FGF13 | c.68del p.P23Lfs*19 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, varscan2
- FOXP1 | c.447dup p.Q150Tfs*20 | Frame Shift Ins (INS) | VAF 30/111 reads (27%) | called by mutect2, pindel, varscan2
- FSTL5 | c.1372del p.Y458Mfs*7 | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- HDAC4 | c.2703del p.M902Wfs*55 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- HDAC4 | c.845del p.K282Sfs*116 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- KIF26A | c.792del p.V265Wfs*43 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- KMT2B | c.481dup p.L161Pfs*23 | Frame Shift Ins (INS) | VAF 18/51 reads (35%) | called by mutect2, pindel, varscan2
- KMT2D | c.2657del p.P886Lfs*44 | Frame Shift Del (DEL) | VAF 36/134 reads (27%) | called by pindel, varscan2
- LRG1 | c.954del p.D319Tfs*17 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- LRSAM1 | c.760_761del p.S254Rfs*3 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by pindel, varscan2
- MAP9 | c.217del p.M73* | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- MBD6 | c.1010del p.P337Lfs*40 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- MED12 | c.5898del p.S1967Afs*19 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- METAP1 | c.711dup p.V238Cfs*6 | Frame Shift Ins (INS) | VAF 28/85 reads (33%) | called by mutect2, pindel, varscan2
- NCOA7 | c.209dup p.R71Efs*4 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- OLFML2B | c.1833del p.W612Gfs*37 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | called by mutect2, pindel, varscan2
- PCDH7 | c.2443A>G p.R815G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PCGF1 | c.20del p.G7Afs*7 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- PDE8A | c.782_784del p.G261del | In Frame Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- PDIA5 | c.1544del p.K515Rfs*18 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- PIK3AP1 | c.2335del p.V779Cfs*32 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- PTPN4 | c.383del p.L128Cfs*22 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | called by mutect2, pindel, varscan2
- RNF123 | c.1652dup p.E552* | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- RSPH3 | c.1165_1167del p.N389del (on ENST00000252655; = p.N247del on NM_031924.8) | In Frame Del (DEL) | VAF 19/65 reads (29%) | called by mutect2, pindel, varscan2
- SHANK1 | c.2076del p.T693Pfs*33 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- SLC38A3 | c.192dup p.K65Efs*66 | Frame Shift Ins (INS) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- SLC4A11 | c.724del p.E242Rfs*18 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.810del p.M272Cfs*31 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, varscan2
- SOGA1 | c.3701del p.P1234Qfs*108 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- SORBS2 | c.2347del p.L783Cfs*64 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- SPTY2D1 | c.96del p.D33Tfs*23 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- TAF1 | c.2749G>A p.A917T (on ENST00000373790 / NM_138923.4; = p.A938T on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- TET3 | c.2939_2941del p.F980del | In Frame Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- TFE3 | c.1445del p.G482Dfs*44 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | called by mutect2, varscan2
- TNS2 | c.1515del p.M506Cfs*14 (on ENST00000314250 / NM_170754.4; = p.M516Cfs*14 on NM_015319.2) | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- TRAV10 | c.8del p.K3Sfs*3 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | called by mutect2, pindel, varscan2
- TRMT2B | c.578dup p.N193Kfs*4 | Frame Shift Ins (INS) | VAF 29/91 reads (32%) | called by mutect2, pindel, varscan2
- ZNF358 | c.345del p.G116Afs*51 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- ZNF526 | c.1966dup p.A656Gfs*3 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- ACBD4 | c.765C>T p.P255= (on ENST00000376955 / NM_001378111.1; = p.R259W on NM_024722.4) | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as rs573177592, COSV100416194; called by muse, mutect2, varscan2
- ACTN2 | c.762C>T p.H254= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs397516584, COSV63971828; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAMTS8 | c.1317C>T p.L439= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99961037; called by muse, mutect2
- ALK | c.3468C>T p.C1156= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as COSV101202100; called by muse, mutect2, varscan2
- ANKRD17 | c.5529A>G p.S1843= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100429323; called by muse, mutect2, varscan2
- BAP1 | c.1923T>C p.A641= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs753767419, COSV99964069; ClinVar: likely benign; called by muse, mutect2, varscan2
- BECN1 | c.645C>T p.V215= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV100831140; called by muse, mutect2, varscan2
- BRPF1 | c.1245G>A p.Q415= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV57404921; called by muse, mutect2, varscan2
- C12orf50 | c.759G>A p.T253= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs776651485, COSV53893183; called by muse, mutect2, varscan2
- CACNA1H | c.843G>A p.T281= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs761655532, COSV61985296; called by muse, mutect2, varscan2
- CALCOCO2 | c.993G>A p.L331= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99363802; called by muse, mutect2, varscan2
- CD74 | c.612C>T p.D204= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs780614932, COSV99153853; called by muse, mutect2, varscan2
- CDCA3 | c.204T>G p.S68= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV99976962; called by muse, mutect2, varscan2
- CDCP2 | c.924C>T p.N308= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as rs770160528, COSV100313511; called by muse, mutect2, varscan2
- CDH23 | c.3591C>T p.Y1197= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs771305669, COSV99819215, COSV99821789; called by muse, mutect2, varscan2
- CDKN2A | c.444G>A p.A148= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs768280139, COSV100446616; called by muse, mutect2, varscan2
- CES3 | c.738G>A p.G246= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100309955; called by muse, mutect2, varscan2
- CHD7 | c.1227T>C p.P409= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV101418268; called by muse, mutect2
- CHPF2 | c.1278G>A p.K426= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99223107; called by muse, mutect2
- CNP | c.195G>A p.T65= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV101102982; called by muse, mutect2, varscan2
- CRYBG1 | c.4551G>A p.V1517= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100954496; called by muse, mutect2, varscan2
- CTDP1 | c.465C>T p.S155= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs767097152, COSV99310699; called by muse, mutect2, varscan2
- CYTH4 | c.561G>A p.V187= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as COSV99957975; called by muse, mutect2, varscan2
- DDX1 | c.6G>A p.A2= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as rs1370569212, COSV99246368; called by muse, mutect2, varscan2
- DHX38 | c.2968C>A p.R990= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as COSV99194335; called by muse, mutect2, varscan2
- DISP3 | c.2739G>A p.K913= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99607551, COSV99609397; called by muse, mutect2, varscan2
- DNER | c.471T>C p.P157= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100519207; called by muse, mutect2, varscan2
- DSE | c.753G>A p.T251= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs769250716, COSV59062569; ClinVar: likely benign; called by muse, mutect2, varscan2
- DVL2 | c.358T>C p.L120= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV99138552; called by muse, mutect2, varscan2
- EARS2 | c.729C>T p.H243= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs577733714, COSV101492171; called by muse, varscan2
- EHD2 | c.1224C>T p.G408= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs756650567, COSV99621998; called by muse, varscan2
- F11R | c.525G>T p.T175= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV57041582, COSV99231072; called by muse, mutect2, varscan2
- F3 | c.114T>G p.T38= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100474284; called by muse, mutect2, varscan2
- F9 | c.834C>T p.V278= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as rs199844858, COSV54379824; ClinVar: benign; called by muse, mutect2, varscan2
- FAM222B | c.1053C>T p.R351= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs762556068, COSV100368578; called by muse, mutect2, varscan2
- FBXO45 | c.315C>A p.A105= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100218092; called by muse, mutect2, varscan2
- FN1 | c.420C>T p.R140= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV60551867; called by muse, mutect2
- FRK | c.1362A>G p.Q454= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV101606658; called by muse, mutect2, varscan2
- GJC2 | c.888C>T p.D296= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV64512596; called by muse, mutect2
- GMPPA | c.777C>T p.R259= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV100354664; called by muse, mutect2, varscan2
- GPR32 | c.705C>T p.C235= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs374423472; called by muse, mutect2, varscan2
- GRM4 | c.375G>A p.A125= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs199504271; called by muse, mutect2, varscan2
- HAPLN1 | c.870C>T p.G290= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99164974; called by muse, mutect2, varscan2
- HDGFL1 | c.174G>A p.P58= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1419818821, COSV100014596; called by muse, mutect2, varscan2
- ICAM1 | c.1452C>T p.I484= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99320867; called by muse, mutect2, varscan2
- IFT27 | c.144A>G p.T48= (on ENST00000433985 / NM_001363003.2; = p.T47= on NM_006860.5) | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100503560; called by muse, mutect2, varscan2
- IGLV3-12 | c.264C>T p.T88= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs758155935; called by muse, mutect2, varscan2
- INTS5 | c.1531C>A p.R511= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100399661; called by muse, mutect2, varscan2
- IQGAP3 | c.486C>T p.Y162= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs752264942, COSV100752169; called by muse, mutect2, varscan2
- ITGA11 | c.1245C>T p.P415= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs372888547; called by muse, mutect2, varscan2
- KANK4 | c.1836G>T p.S612= | Silent (SNP) | VAF 8/137 reads (6%) | catalogued as rs1008296046, COSV100587409; called by muse, mutect2
- KCTD19 | c.2679C>A p.P893= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV58573674; called by muse, mutect2, varscan2
- KIF26A | c.2109G>A p.S703= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs914704307, COSV100181194, COSV59464704; called by muse, mutect2, varscan2
- KLC2 | c.1707C>T p.P569= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1176993735, COSV100270565, COSV100270748; called by muse, mutect2, varscan2
- KRT73 | c.1131C>T p.A377= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV99988561; called by muse, mutect2, varscan2
- LONRF2 | c.1665C>T p.H555= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs759509727, COSV101110961; called by muse, mutect2, varscan2
- LRFN2 | c.627G>A p.L209= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs567768191, COSV100599614; called by muse, mutect2, varscan2
- LRP12 | c.1455C>T p.C485= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV52630556; called by muse, mutect2, varscan2
- LRRC41 | c.1629C>T p.I543= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs1203538430, COSV100586397; called by muse, mutect2
- LTBP1 | c.4734C>T p.N1578= (on ENST00000404816 / NM_206943.4; = p.N1252= on NM_000627.4) | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV99698345; called by muse, mutect2, varscan2
- LTBP2 | c.2724C>A p.S908= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100000425; called by muse, mutect2
- MEGF8 | c.4263C>T p.C1421= (on ENST00000251268 / NM_001271938.2; = p.C1354= on NM_001410.3) | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs1028636692, COSV99236681; called by muse, mutect2, varscan2
- METTL2B | c.54G>A p.Q18= | Silent (SNP) | VAF 31/100 reads (31%) | catalogued as rs759777322, COSV99299848; called by muse, mutect2, varscan2
- MLLT10 | c.150G>A p.A50= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100308224; called by muse, mutect2, varscan2
- MLXIPL | c.522C>T p.I174= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs781966362, COSV100515380; called by muse, mutect2, varscan2
- MPO | c.1129C>T p.L377= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99832734; called by muse, mutect2, varscan2
- MYBL2 | c.687C>A p.P229= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99406417; called by muse, mutect2, varscan2
- MYOD1 | c.660C>T p.A220= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100000281; called by muse, mutect2, varscan2
- NID1 | c.2643C>T p.H881= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs1442734608, COSV99936997; called by muse, mutect2, varscan2
- NLRP14 | c.3006C>T p.C1002= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV100205062; called by muse, mutect2, varscan2
- NOMO3 | c.504C>T p.G168= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1410357996, COSV99530838; called by mutect2, varscan2
- NPAP1 | c.3096A>G p.T1032= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV61512223; called by muse, mutect2, varscan2
- OR56A3 | c.576C>A p.S192= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100289936, COSV100290251; called by muse, mutect2, varscan2
- OSBPL7 | c.1077C>T p.S359= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs368690330, COSV50114203; called by muse, varscan2
- OTUD7B | c.2290T>C p.L764= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100967588; called by muse, mutect2, varscan2
- OXGR1 | c.531G>A p.R177= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100037020; called by muse, mutect2, varscan2
- PCDHB5 | c.1419C>T p.S473= | Silent (SNP) | VAF 56/171 reads (33%) | catalogued as rs782525128, COSV50650116; called by muse, mutect2, varscan2
- PCDHB6 | c.1887C>T p.S629= | Silent (SNP) | VAF 11/140 reads (8%) | catalogued as COSV99170175; called by muse, mutect2
- PCDHGB1 | c.1413C>T p.S471= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs746872217, COSV53940736, COSV99542469; called by muse, varscan2
- PCGF6 | c.285G>A p.E95= | Silent (SNP) | VAF 50/155 reads (32%) | catalogued as rs1564737554, COSV100461591; called by muse, mutect2, varscan2
- PFAS | c.2217C>T p.A739= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs368550397; called by muse, mutect2, varscan2
- PGGHG | c.951C>T p.A317= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs777435493, COSV67141703; called by muse, mutect2, varscan2
- PITPNM2 | c.1002C>T p.A334= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99759092; called by muse, mutect2, varscan2
- PLEKHH3 | c.2049G>A p.L683= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1331003377, COSV99257624; called by muse, mutect2, varscan2
- PLEKHH3 | c.942C>T p.G314= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs369583008, COSV99512047; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2364G>A p.Q788= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99461384; called by muse, mutect2, varscan2
- PPP1R12C | c.795C>T p.H265= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs374570333; called by muse, mutect2, varscan2
- PRDM16 | c.453G>T p.L151= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99577015; called by muse, mutect2, varscan2
- PRKX | c.639C>T p.P213= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs750781693, COSV99468142; called by muse, varscan2
- PRPF19 | c.777C>A p.T259= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV99920634; called by muse, mutect2
- PRUNE2 | c.2907C>A p.T969= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV100944671; called by muse, mutect2
- RNF145 | c.1359T>C p.Y453= (on ENST00000424310 / NM_001199383.2; = p.Y481= on NM_144726.2) | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99193572; called by muse, mutect2, varscan2
- ROS1 | c.255C>T p.S85= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV100877151; called by muse, mutect2, varscan2
- RPS6KA1 | c.1599C>T p.H533= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV100943140; called by muse, mutect2, varscan2
- RREB1 | c.1822C>T p.L608= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs758121441, COSV100619417; called by muse, mutect2, varscan2
- RRM1 | c.1461T>C p.P487= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs572098942, COSV100331323; called by muse, mutect2, varscan2
- RTF2 | c.318T>G p.T106= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99196506; called by muse, mutect2, varscan2
- RUNDC1 | c.1647G>A p.Q549= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100865857; called by muse, mutect2, varscan2
- SAP130 | c.1059A>G p.L353= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV99384770; called by muse, mutect2, varscan2
- SBDS | c.513C>T p.H171= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV99886051; called by muse, mutect2, varscan2
- SCN10A | c.2553T>C p.I851= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV101479418; called by muse, varscan2
- SECISBP2 | c.852C>T p.A284= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs375427767; called by muse, varscan2
- SHD | c.69G>A p.P23= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs368711499, COSV101619040; called by muse, mutect2, varscan2
- SHTN1 | c.912C>T p.H304= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as rs771681541, COSV99598967; called by muse, mutect2, varscan2
- SLC2A4 | c.1419C>T p.G473= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV99142723; called by muse, mutect2, varscan2
- SLC30A2 | c.39G>A p.R13= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100958557; called by muse, mutect2, varscan2
- SLC4A10 | c.1854C>T p.C618= (on ENST00000446997 / NM_001354461.2; = p.C588= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV99764428; called by muse, mutect2, varscan2
- SMARCE1 | c.121C>T p.L41= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV100796025; called by muse, mutect2
- SNAP47 | c.1270C>T p.L424= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100248216; called by muse, mutect2, varscan2
- SRRT | c.744G>A p.K248= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV100730164; called by muse, mutect2, varscan2
- SYNE1 | c.24774C>A p.S8258= (on ENST00000367255 / NM_182961.4; = p.S8187= on NM_033071.3) | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99566684; called by muse, mutect2, varscan2
- TAS2R30 | c.174G>A p.L58= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs776753536, COSV101114959; called by muse, mutect2, varscan2
- TDRD1 | c.2808G>A p.L936= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV99314624; called by muse, mutect2, varscan2
- TRHR | c.1005C>T p.C335= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100304879; called by muse, mutect2, varscan2
- TRIM22 | c.1294T>C p.L432= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV101181369; called by muse, mutect2, varscan2
- TTN | c.70245C>G p.A23415= (on ENST00000591111; = p.A15991= on NM_003319.4) | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV60027826; called by muse, mutect2, varscan2
- TTN | c.57231G>A p.V19077= (on ENST00000591111; = p.V11653= on NM_003319.4) | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100616073; called by muse, mutect2, varscan2
- TTN | c.22317T>C p.D7439= (on ENST00000591111; = p.D6512= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100616075, COSV60225280; called by muse, mutect2, varscan2
- VCX | c.300G>A p.Q100= | Silent (SNP) | VAF 20/214 reads (9%) | catalogued as COSV100406302; called by muse, mutect2
- VCX2 | c.300G>A p.Q100= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100400060; called by muse, mutect2
- XAF1 | c.211C>T p.L71= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100695102; called by muse, varscan2
- YLPM1 | c.1020T>C p.S340= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99459843; called by muse, mutect2, varscan2
- ZBTB17 | c.2001C>T p.T667= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs753306123, COSV100999025; called by muse, mutect2, varscan2
- ZC3H11A | c.363G>A p.Q121= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV100142403; called by muse, mutect2, varscan2
- ZC3H12D | c.153G>A p.E51= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV101116923; called by muse, mutect2, varscan2
- ZFP64 | c.1683G>A p.A561= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs201143929; called by muse, mutect2, varscan2
- ZNF419 | c.660G>A p.Q220= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV55657518; called by muse, mutect2, varscan2
- ZNF586 | c.999T>C p.I333= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV101197686; called by muse, mutect2, varscan2
- ZNF646 | c.162G>A p.G54= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1555499172, COSV100336700; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823055 del T | 5'Flank (DEL) | VAF 20/78 reads (26%) | catalogued as rs755255238; called by mutect2, varscan2
- BCAS3 | c.2639-3337del | Intron (DEL) | VAF 10/23 reads (43%) | catalogued as rs749349621, COSV66776673; called by mutect2, varscan2
- BCR | c.1279+16039G>A | Intron (SNP) | VAF 32/97 reads (33%) | catalogued as rs764057926; called by muse, mutect2
- CAPN1 | chr11:65214015 C>A | 3'Flank (SNP) | VAF 30/94 reads (32%) | catalogued as rs764187175; called by muse, mutect2, varscan2
- CARD14 | c.1851+31G>A | Intron (SNP) | VAF 23/67 reads (34%) | catalogued as rs756197625, COSV100712569; called by muse, mutect2, varscan2
- EPB41L3 | chr18:5630451 ins A | 5'Flank (INS) | VAF 20/86 reads (23%) | catalogued as rs951108873; called by mutect2, varscan2
- GCNT2 | c.925+27347del | Intron (DEL) | VAF 6/21 reads (29%) | called by mutect2, varscan2
- HMGB1P1 | n.564G>A | RNA (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- LHFPL3 | c.-16C>T | 5'UTR (SNP) | VAF 14/26 reads (54%) | catalogued as COSV101308410; called by muse, mutect2, varscan2
- LINC02870 | n.77C>A | RNA (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- PHKA1 | c.-2C>T | 5'UTR (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100263358; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1574C>T | RNA (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- RBFOX1 | c.28-185091C>T | Intron (SNP) | VAF 15/53 reads (28%) | catalogued as rs773668882, COSV100301679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNORD116-4 | n.28del | RNA (DEL) | VAF 26/98 reads (27%) | catalogued as rs753149037; called by mutect2, varscan2
- STMP1 | chr7:135660556 G>A | 5'Flank (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
